Somatic mutation profile of tumor specimen 0E0A0D from CCDI case PBCVCK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E0A0D: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b5779ec9-4e8a-453c-93b5-df968ad0c3c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E0A0T (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a847ac8c-3574-4423-94d8-5c67c253d1bb

The open-access MAF lists 55 somatic variants for this specimen: 32 protein-altering or splice-affecting, 12 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 12, Intron 8, Frame Shift Del 3, Splice Site 2, 3'UTR 2, Nonsense Mutation 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 523/838 reads (62%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARSH | c.779C>G p.P260R | Missense Mutation (SNP) | VAF 219/525 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101139735, COSV66963762; called by muse, mutect2, varscan2
- CLCC1 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 246/805 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs762290790; called by muse, varscan2
- FAM124A | c.1036C>G p.R346G (on ENST00000322475 / NM_001242312.2; = p.R382G on NM_145019.4) | Missense Mutation (SNP) | VAF 171/695 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.331); catalogued as rs201443401, COSV99696093; called by muse, mutect2, varscan2
- FSTL5 | c.1957G>A p.A653T | Missense Mutation (SNP) | VAF 155/649 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs1217808238, COSV100056727; called by muse, mutect2, varscan2
- GABRA3 | c.1007C>T p.T336M | Missense Mutation (SNP) | VAF 192/486 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64801472; called by muse, mutect2, varscan2
- ITPKB | c.1198G>C p.V400L | Missense Mutation (SNP) | VAF 100/605 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as rs374593738; called by muse, mutect2, varscan2
- KAT14 | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 273/1349 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as rs137920496; called by muse, mutect2, varscan2
- LRRC49 | c.920C>T p.T307M | Missense Mutation (SNP) | VAF 136/452 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs753124747, COSV99536806; called by muse, mutect2, varscan2
- NYX | c.944C>T p.T315I | Missense Mutation (SNP) | VAF 95/202 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1262614477; called by muse, mutect2, varscan2
- PCNX1 | c.840del p.R281Efs*18 | Frame Shift Del (DEL) | VAF 188/703 reads (27%) | catalogued as COSV99455845; called by mutect2, varscan2
- PPP2R3C | c.67del p.S23Vfs*5 | Frame Shift Del (DEL) | VAF 104/724 reads (14%) | catalogued as rs758484975; called by mutect2, varscan2
- RBP3 | c.1657G>A p.A553T | Missense Mutation (SNP) | VAF 100/235 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.536); catalogued as rs782217999; called by muse, mutect2, varscan2
- UCHL5 | c.979G>T p.E327* | Nonsense Mutation (SNP) | VAF 248/1754 reads (14%) | catalogued as COSV66485656, COSV66486868; called by muse, mutect2, varscan2
- BAZ1A | c.470A>T p.D157V | Missense Mutation (SNP) | VAF 136/880 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BIK | c.16C>G p.P6A | Missense Mutation (SNP) | VAF 110/437 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- CFL2 | c.41T>A p.V14D | Missense Mutation (SNP) | VAF 240/1240 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- CYP39A1 | c.1388T>C p.I463T | Missense Mutation (SNP) | VAF 218/1272 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- DAB1 | c.1062G>T p.M354I (on ENST00000371231; = p.M321I on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 150/489 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERVV-2 | c.958dup p.R320Kfs*27 | Frame Shift Ins (INS) | VAF 20/60 reads (33%) | called by mutect2, varscan2
- EXOC3 | c.1584C>G p.D528E | Missense Mutation (SNP) | VAF 140/306 reads (46%) | SIFT tolerated (0.61); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- FSD1 | c.15+1G>T p.X5_splice | Splice Site (SNP) | VAF 25/75 reads (33%) | called by muse, mutect2, varscan2
- FZD5 | c.410C>G p.P137R | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA1958 | c.2036G>T p.R679L | Missense Mutation (SNP) | VAF 67/169 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- MUC16 | c.34406C>A p.T11469K | Missense Mutation (SNP) | VAF 135/425 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- NXPH2 | c.52-2A>T p.X18_splice | Splice Site (SNP) | VAF 91/274 reads (33%) | called by muse, mutect2, varscan2
- PDS5B | c.1961A>G p.K654R | Missense Mutation (SNP) | VAF 128/484 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- PPM1J | c.761A>G p.H254R | Missense Mutation (SNP) | VAF 252/855 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTPRU | c.3341A>G p.Y1114C | Missense Mutation (SNP) | VAF 141/516 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RASGRP3 | c.322C>A p.Q108K | Missense Mutation (SNP) | VAF 205/786 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TAF4 | c.1306_1318del p.P437Rfs*26 | Frame Shift Del (DEL) | VAF 73/517 reads (14%) | called by mutect2, varscan2
- UBQLN2 | c.651A>T p.R217S | Missense Mutation (SNP) | VAF 26/517 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.28); called by muse, mutect2
- BGLAP | c.297G>A p.P99= | Silent (SNP) | VAF 48/343 reads (14%) | catalogued as rs1212343027, COSV52746720; called by muse, mutect2, varscan2
- BMPER | c.1128C>T p.D376= | Silent (SNP) | VAF 303/739 reads (41%) | catalogued as rs1400459857, COSV51814336; called by muse, mutect2, varscan2
- CUL5 | c.1404C>T p.A468= | Silent (SNP) | VAF 238/918 reads (26%) | catalogued as rs149384884; called by muse, mutect2, varscan2
- DIO2 | c.129C>G p.R43= | Silent (SNP) | VAF 196/691 reads (28%) | called by muse, mutect2, varscan2
- GPR143 | c.489C>A p.G163= | Silent (SNP) | VAF 145/451 reads (32%) | called by muse, mutect2, varscan2
- HERC1 | c.525A>G p.Q175= | Silent (SNP) | VAF 350/635 reads (55%) | called by muse, mutect2, varscan2
- NEK7 | c.102T>C p.F34= | Silent (SNP) | VAF 235/1411 reads (17%) | called by muse, varscan2
- NOP56 | c.1194A>G p.R398= | Silent (SNP) | VAF 268/1625 reads (16%) | called by muse, mutect2, varscan2
- OR13C2 | c.357C>G p.A119= | Silent (SNP) | VAF 81/247 reads (33%) | called by muse, mutect2, varscan2
- RHBDL2 | c.717T>C p.P239= | Silent (SNP) | VAF 145/558 reads (26%) | called by muse, mutect2, varscan2
- RHOT2 | c.1620C>T p.A540= | Silent (SNP) | VAF 202/452 reads (45%) | catalogued as rs374145652; called by muse, mutect2, varscan2
- TP53BP2 | c.1236C>T p.I412= (on ENST00000343537 / NM_001031685.3; = p.I283= on NM_005426.2) | Silent (SNP) | VAF 171/1005 reads (17%) | catalogued as rs369989893; called by muse, mutect2, varscan2
- APLP1 | c.148-29C>A | Intron (SNP) | VAF 20/80 reads (25%) | called by muse, mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 11/203 reads (5%) | called by muse, mutect2
- CYB5R2 | c.559-58G>C | Intron (SNP) | VAF 42/148 reads (28%) | called by muse, varscan2
- DPY19L2 | c.*20A>G | 3'UTR (SNP) | VAF 89/283 reads (31%) | catalogued as rs761555604; called by muse, mutect2, varscan2
- HSPA8 | c.1323+27G>A | Intron (SNP) | VAF 103/328 reads (31%) | catalogued as COSV57086901; called by muse, mutect2, varscan2
- MED13L | c.2570-24A>T | Intron (SNP) | VAF 198/625 reads (32%) | catalogued as rs766244256; called by muse, mutect2, varscan2
- PPIC | c.*95T>C | 3'UTR (SNP) | VAF 47/75 reads (63%) | called by muse, mutect2, varscan2
- PRUNE2 | c.8276+11277G>T | Intron (SNP) | VAF 89/204 reads (44%) | called by muse, mutect2, varscan2
- SNRPG | c.-48G>C | 5'UTR (SNP) | VAF 99/325 reads (30%) | catalogued as rs763792385; called by muse, mutect2, varscan2
- SNX22 | c.75+81C>T | Intron (SNP) | VAF 6/18 reads (33%) | catalogued as rs1296964039; called by muse, mutect2, varscan2
- TAF10 | c.233-12G>C | Intron (SNP) | VAF 124/469 reads (26%) | called by muse, mutect2, varscan2
